Surgical pathology report (de-identified scan), TCGA case TCGA-WC-A882, project TCGA-UVM (Uveal Melanoma), tissue source site MD Anderson, specimen TCGA-WC-A882-01A (Primary Tumor).

Specimen Date/Time:

ICD-0-3

Melanoma, spindle cell
8772/3

DIAGNOSIS

(A) RIGHT GLOBE:

(> 90%)

CILIOCHOROIDAL MELANOMA, SPINDLED TYPE, 12 MM BASE
MINIMAL SCLERAL INVASION
Vortex veins negative for tumor
Optic nerve negative for tumor
Extraocular extension is not identified.
See comment.

Site: Overlapping lesion of eye
4 adnexa C69.8

QW 1/16/14

COMMENT

The tumor does not involve the canal of schlemm. Mitoses are low (< 1 per 10 HPF). A PAS was reviewed and highlights its structures.

GROSS DESCRIPTION

(A) RIGHT GLOBE – An intact right eye (23 mm anterior to posterior x 22 mm horizontally x 22 mm vertically), has an attached optic nerve (6 mm in length). The cornea is clear (12 mm horizontally x 12 mm vertically). The anterior chamber is clear and formed by a tan-gray iris with a round 6 mm in diameter pupil. Sclera is unremarkable. On transillumination, a shadow from 9 o'clock hours beginning at the limbus and extending to 12 mm from the optic nerve, corresponds to a tumor. The eye is open vertically. The lens is transparent. The vitreous is clear. A tan-brown tumor, 12 x 10 mm base x 8 height, involves the ciliary body and the choroid. The sclera beneath the tumor is grossly intact. Tissue is harvest per protocol.

SECTION CODE: A1, superior temporal vortex vein; A2, superior nasal vortex vein; A3, inferior nasal vortex vein; A4, inferior temporal vortex vein; A5, pupil optic nerve section; A6, A7, nasal/temporal calotte; A8, optic nerve cross section, maxillary face.

CLINICAL HISTORY

None given.

SNOMED CODES

T-AA000, M-2703

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by: _____

These tests have no

-----END OF REPORT-----

[illegible]

Source: NCI Genomic Data Commons file b185ea78-4851-4606-a6e2-c8a3d4e0207b (TCGA-WC-A882.BCFE115C-4472-4221-86B3-75B122F9B425.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).